Gene-level copy-number profile of tumor specimen C3L-00561-01 from CPTAC case C3L-00561, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 50.6 years (18,481 days).
Specimen C3L-00561-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 06cfbfb2-b47d-4ec2-88fa-11638ce8a0b3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00561-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/0ad3b2f4-797f-4021-b0b5-43fd90edc181

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,455; copy number 2: 31,148; copy number 3: 20,353; copy number 4: 3,541; copy number 5: 1,404.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:71,395,943–72,282,539, 5 genes (within-gene range 0–2): NEGR1, AL354949.1, AL359821.1, NEGR1-IT1, GDI2P2.
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr11:84,545,131–84,546,846, 1 gene (within-gene range 0–2): HNRNPA1P72.
- chr14:79,072,132–79,249,023, 3 genes (within-gene range 0–1): AC026888.1, AC022469.1, AC022469.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,404 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:52,622,458–145,066,685, 1,404 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,445. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
